CCDI case PBBRHB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0d6ad768-de2b-4c1e-a075-6c2c67226d27

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 14.4 years (5,261 days).

Biospecimens (3 samples)
- Sample 0DEV2E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEV3Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEV4D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
